Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4X9, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4X9-01A (Primary Tumor).

[page 1 of 2]
Proc

Rec

Rep

Final Diagnosis:

A-B. Brain, left temporal lobe, biopsies: WHO grade II (of III) oligoastrocytoma, astrocytic-dominant. Only 1 mitosis is noted per 10 high power fields. Neither endothelial hyperplasia nor proliferation is seen nor is necrosis. See separate stain report.

Stain report:

Vimentin: The reaction is largely negative.

MIB-1: The labeling index is focally moderate.

p53: Positivity is noted in numerous neoplastic cells.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the

1CD-0-3

Oligoastrocytoma 9382/3

Site: brain, temporal lobe C71-2

fw
10/23/12

Preliminary Frozen Section Consultation:

[page 2 of 2]
A. Brain, left temporal lobe #1, smears: Low-grade glioma. Hold over to confirm and share with
Seen in consultation with

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "left temporal lobe lesion" is a 1.1 x 0.9 x 0.3 cm aggregate of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "left temporal lobe lesion #2" is a 7.5 x 4.4 x 2.2 cm aggregate of brain. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left temporal lobe lesion

1 Left temporal lobe lesion

Part B: Left temporal lobe lesion#2

1 Lt temporal lesion #2-1

2 Lt temporal lesion #2-2

3 Lt temporal lesion #2-3

4 Lt temporal lesion #2-4

END OF REPORT

Prior Pathology History		☒

10/23/12

Source: NCI Genomic Data Commons file 5524199c-411b-4af9-89ab-7ad639e5189d (TCGA-DB-A4X9.8C541033-3F59-4F35-9BA8-C5499B944094.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).